Somatic mutation profile of tumor specimen MBCProject_0040_T2_WES (aliquot MBCProject_0040_T2_WES_1) from CMI case MBCProject_0040, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0040_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c1b65c9-894b-4076-806e-599081a0eb57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0040_SALIVA (Saliva), aliquot MBCProject_0040_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60b2eb77-0cdf-403f-bb62-70de1b323c70

The open-access MAF lists 475 somatic variants for this specimen: 309 protein-altering or splice-affecting, 105 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 271, Silent 105, Intron 30, Nonsense Mutation 27, RNA 9, 3'UTR 9, 5'UTR 7, Splice Site 6, 3'Flank 4, Splice Region 3, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as CM120215, COSV99522036; called by muse, mutect2, varscan2
- ANGPT4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as rs762925133, COSV67922731; called by muse, mutect2, varscan2
- ANXA5 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380635484; called by muse, mutect2, varscan2
- APBB1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.925); catalogued as rs1326780556; called by muse, varscan2
- ARHGEF40 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs369039824; called by muse, mutect2
- ARSK | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.232); catalogued as rs761530133; called by muse, mutect2, varscan2
- ATRX | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs781803934, COSV64869902; called by muse, mutect2, varscan2
- C1QTNF2 | c.340G>C p.D114H (on ENST00000393975; = p.D69H on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1462062656; called by muse, mutect2
- C1QTNF8 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs536775061, COSV60518779; called by muse, varscan2
- C1orf141 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as rs1338845467; called by muse, mutect2
- C1orf21 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.859); catalogued as COSV52404355; called by muse, mutect2, varscan2
- CCDC138 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1405119455; called by muse, mutect2
- CCDC146 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 29/208 reads (14%) | catalogued as COSV53544341; called by muse, mutect2, varscan2
- CCNT2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51470870; called by muse, mutect2, varscan2
- CDH4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 45/485 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs368305378; called by muse, mutect2
- CDK12 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT tolerated, low confidence (0.71); PolyPhen possibly damaging (0.867); catalogued as rs796501956, COSV71002995, COSV71003355; called by muse, mutect2
- CKAP2L | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754317985; called by muse, mutect2, varscan2
- CNDP1 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100722509, COSV62593269; called by muse, mutect2, varscan2
- COX19 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as rs1562946496; called by muse, mutect2
- CPB1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as rs375725355; called by muse, mutect2, varscan2
- CYP3A5 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV56122275; called by muse, mutect2, varscan2
- DENND2C | c.2458G>A p.E820K (on ENST00000393274 / NM_001256404.2; = p.E763K on NM_198459.4) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780932484, COSV67921285; called by muse, mutect2, varscan2
- DMRT3 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1261539213, COSV51903809; called by muse, mutect2, varscan2
- DSC1 | c.2163G>C p.K721N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV57151051; called by muse, mutect2, varscan2
- DTX4 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.07); catalogued as COSV99914871; called by muse, mutect2, varscan2
- ELOA2 | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55309949; called by muse, mutect2
- EMSY | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); catalogued as COSV100595800, COSV100595856, COSV100596116; called by muse, mutect2
- ENDOU | c.815C>G p.S272* (on ENST00000422538 / NM_001172439.2; = p.S231* on NM_006025.4) | Nonsense Mutation (SNP) | VAF 37/228 reads (16%) | catalogued as rs775527125, COSV99968378; called by muse, mutect2, varscan2
- EPHB6 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV63890555; called by muse, mutect2, varscan2
- FLG | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.914); catalogued as COSV64248850; called by muse, mutect2, varscan2
- FOXP2 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.942); catalogued as COSV63484215; called by muse, mutect2, varscan2
- FOXP2 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63495346; called by muse, mutect2, varscan2
- GLRA1 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV51008427; called by muse, mutect2, varscan2
- GP2 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as rs766928422; called by muse, mutect2, varscan2
- GSTZ1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs202037445; called by muse, mutect2, varscan2
- GTF3C5 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59601231; called by muse, mutect2, varscan2
- GYPB | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV51622735; called by muse, mutect2, varscan2
- H2BU1 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1292893708; called by muse, mutect2, varscan2
- HARS2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1386383653, COSV56910320; called by muse, mutect2, varscan2
- HEPACAM | c.1175C>G p.S392W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV99035979; called by muse, mutect2, varscan2
- HOMEZ | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.166); catalogued as rs1483023822; called by muse, mutect2, varscan2
- HTR1A | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 55/361 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV60501438, COSV60502125; called by muse, mutect2, varscan2
- IDUA | c.1759C>G p.Q587E | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56106012; called by muse, mutect2, varscan2
- IRS1 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV59335521; called by muse, mutect2, varscan2
- IRX4 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); catalogued as COSV51472493; called by muse, mutect2, varscan2
- ITPRID2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1292558135; called by muse, mutect2, varscan2
- JAK2 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV67663615; called by muse, mutect2, varscan2
- KCNK13 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as COSV56411546, COSV56413751; called by muse, mutect2, varscan2
- KCTD19 | c.2171G>C p.R724T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs1217943920; called by muse, mutect2
- LAMA5 | c.6460C>T p.P2154S | Missense Mutation (SNP) | VAF 58/714 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99442423; called by muse, mutect2
- LOXHD1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs1394542147; called by muse, mutect2, varscan2
- LRRN4CL | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99042307; called by muse, mutect2, varscan2
- LYST | c.581C>G p.S194W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.315); catalogued as rs997647491, COSV101090203; called by muse, mutect2, varscan2
- MAP1A | c.4180C>G p.L1394V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV100287941; called by muse, mutect2, varscan2
- MET | c.3902G>C p.R1301T | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59272207; called by muse, mutect2, varscan2
- MINK1 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as rs780075596; called by mutect2, varscan2
- MIPOL1 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs930100080; called by muse, mutect2, varscan2
- MTAP | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs569692278; called by muse, mutect2, varscan2
- MYT1L | c.2472G>A p.M824I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV67728932; called by muse, mutect2, varscan2
- NRP2 | c.1806G>C p.E602D | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.97); catalogued as COSV99075693; called by muse, mutect2, varscan2
- NT5DC1 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1227103381; called by muse, mutect2, varscan2
- NUDT17 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57908811; called by muse, mutect2, varscan2
- OBSCN | c.8636C>T p.T2879M | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs113115515, COSV52782963; called by muse, mutect2, varscan2
- OR10Z1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368757079; called by muse, mutect2, varscan2
- PAN2 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57756536; called by muse, mutect2
- PCM1 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs766231190, COSV100279224; called by muse, mutect2, varscan2
- PDK1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs748428552, COSV99961273; called by muse, mutect2, varscan2
- PDXDC1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as COSV57911291; called by muse, mutect2, varscan2
- PIAS2 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61343290; called by muse, mutect2, varscan2
- PIGV | c.891C>A p.F297L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1057518270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57133614; called by muse, mutect2, varscan2
- PLA2G2C | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs747786520, COSV56125240; called by muse, mutect2, varscan2
- PMS2 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV56151812; called by muse, mutect2, varscan2
- POGK | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV63312029; called by muse, mutect2, varscan2
- PPP4R3A | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV61506089; called by muse, mutect2, varscan2
- PREP | c.360C>G p.F120L (on ENST00000369110; = p.F186L on NM_002726.5) | Missense Mutation (SNP) | VAF 41/1234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64872775; called by muse, mutect2
- PRICKLE1 | c.2011C>A p.H671N | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs776619006, COSV100453357; called by muse, mutect2, varscan2
- PRKG1 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99059509; called by muse, mutect2, varscan2
- PTDSS2 | c.1230C>G p.F410L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100339119; called by muse, mutect2, varscan2
- RBM8A | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57162039, COSV57162381; called by muse, mutect2
- RUSC1 | c.1812C>G p.L604= (on ENST00000368352 / NM_001105203.2; = p.L135= on NM_014328.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 47/146 reads (32%) | catalogued as COSV99430153; called by muse, mutect2, varscan2
- RXFP4 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV100563546; called by muse, mutect2, varscan2
- SCARA3 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV57269155; called by muse, mutect2, varscan2
- SLC10A1 | c.732C>G p.F244L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53682560; called by muse, mutect2, varscan2
- SLC25A46 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV63506421, COSV63506435; called by muse, mutect2, varscan2
- SLF1 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1222930975; called by muse, mutect2, varscan2
- SYNM | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs1555483618; called by muse, mutect2, varscan2
- TCHH | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.125); catalogued as COSV64277925; called by muse, mutect2, varscan2
- TDRD5 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV54248611; called by muse, mutect2
- TFAP4 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1567203979, COSV52597523; called by muse, mutect2
- TLR4 | c.260+1G>A p.X87_splice (on ENST00000355622 / NM_138554.5; = p.X47_splice on NM_003266.4) | Splice Site (SNP) | VAF 43/68 reads (63%) | catalogued as COSV100790650, COSV62923432; called by muse, mutect2, varscan2
- TMEM161A | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1175051975; called by muse, mutect2
- VPS25 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV53821375; called by muse, varscan2
- WAPL | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 9/136 reads (7%) | catalogued as COSV100076549, COSV53938802; called by muse, mutect2
- XIRP2 | c.3973G>C p.D1325H (on ENST00000628543; = p.D1500H on NM_152381.6) | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706385; called by muse, mutect2, varscan2
- ZBTB20 | c.511C>G p.L171V (on ENST00000474710 / NM_001164342.2; = p.L98V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61844920; called by muse, mutect2, varscan2
- ZC3H12C | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.166); catalogued as rs1476761609; called by muse, mutect2, varscan2
- ZFHX4 | c.5005G>C p.E1669Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV50870152; called by muse, mutect2, varscan2
- ZFP64 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 34/531 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV53799418; called by muse, mutect2
- ZFYVE16 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs976981801; called by muse, mutect2, varscan2
- ZNF217 | c.2602C>G p.P868A | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56597167; called by muse, mutect2, varscan2
- ZNF579 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV57637619; called by muse, mutect2
- ABCA3 | c.4723G>C p.E1575Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABTB1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ACCS | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by mutect2, varscan2
- ACOD1 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACRBP | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by mutect2, varscan2
- ADRA1A | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AKR1E2 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AL035078.4 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- AL162231.1 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALKBH3 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- ALMS1 | c.12065G>C p.R4022T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ALOX15B | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2
- ANKRD16 | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD18A | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD50 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- APOB | c.11878G>C p.E3960Q | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARAP3 | c.3192C>G p.F1064L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ARFRP1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 57/612 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP4 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ARHGAP9 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ARHGEF10 | c.855G>C p.Q285H (on ENST00000398564; = p.Q260H on NM_014629.4) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATF3 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- B4GALNT1 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- BAG6 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- BDP1 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- BICDL1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- BIRC6 | c.3274G>C p.E1092Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2
- C11orf80 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACNA1H | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CADPS2 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CAPN9 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC91 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CCDC9B | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2
- CCNJL | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CCNK | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDH4 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- CEP76 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CERKL | c.1531G>A p.E511K (on ENST00000339098 / NM_001030311.2; = p.E485K on NM_201548.5) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP299 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CHFR | c.1942C>T p.H648Y (on ENST00000432561 / NM_001161345.1; = p.H607Y on NM_018223.2) | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CILP2 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CLHC1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL13A1 | c.1693G>C p.E565Q (on ENST00000398978 / NM_001130103.2; = p.E546Q on NM_080800.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.303); called by muse, mutect2
- CPA1 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CPD | c.3286G>C p.D1096H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPN1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CSMD1 | c.1671del p.F558Lfs*52 (on ENST00000520002; = p.F557Lfs*52 on NM_033225.6) | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9322G>A p.E3108K (on ENST00000297405 / NM_001363185.1; = p.E2939K on NM_052900.3) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CTSO | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTSO | c.342G>C p.W114C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.9056C>G p.S3019C | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- DAB2 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- DIDO1 | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DIPK1A | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- DLG1 | c.2514C>T p.I838= (on ENST00000419354 / NM_001290983.1; = p.I860= on NM_004087.2) | Splice Region (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2
- DNAH14 | c.8568G>C p.L2856F (on ENST00000445597; = p.L3659F on NM_001367479.1) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DYNLRB2 | c.110C>G p.S37* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- EGF | c.2699C>G p.S900* | Nonsense Mutation (SNP) | VAF 46/190 reads (24%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1544G>A p.R515K (on ENST00000346169 / NM_198241.3; = p.R319K on NM_004953.5) | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EML5 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EPB42 | c.1763C>T p.P588L (on ENST00000441366 / NM_001114134.2; = p.P618L on NM_000119.3) | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- EPHB6 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ETV7 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EYS | c.1948G>C p.A650P | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM186A | c.2511G>C p.M837I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FARSB | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FASTK | c.686-8C>T | Splice Region (SNP) | VAF 43/277 reads (16%) | called by muse, mutect2, varscan2
- FCMR | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FHAD1 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL3 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by mutect2, varscan2
- FOXO3 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2, varscan2
- FRYL | c.4613G>T p.G1538V | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT13 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.068); called by muse, mutect2
- GALR3 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GFOD2 | c.816C>G p.N272K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GIP | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLCE | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- GRB14 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTK1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GTF3C1 | c.1912C>G p.Q638E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- GTPBP3 | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GUCY2C | c.1408C>G p.H470D | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUSB | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- H2AW | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5A | c.5839C>T p.Q1947* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2
- HELZ | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- HIBCH | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- HLA-DQA2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, varscan2
- HMCN1 | c.7683G>C p.R2561S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HSPA4 | c.1248C>G p.D416E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2
- HYAL4 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IDO1 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IGSF11 | c.855-1G>C p.X285_splice (on ENST00000393775 / NM_001015887.3; = p.X284_splice on NM_152538.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- IRX2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KCNA4 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- KIF13B | c.4402C>G p.L1468V | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF21B | c.3132+1G>A p.X1044_splice | Splice Site (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- LAMB1 | c.4312C>G p.H1438D | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOXL3 | c.879G>T p.Q293H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- LRP12 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- LRRC75B | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LRRD1 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MACF1 | c.8962G>C p.E2988Q | Missense Mutation (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- MOB2 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MORC1 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MPHOSPH9 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- MRPS24 | c.380T>C p.L127S | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MS4A18 | c.766C>G p.L256V (on ENST00000398983; = p.L258V on NM_001354471.1) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MUC13 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC5B | c.11662C>G p.P3888A | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYBPC1 | c.1726G>C p.E576Q (on ENST00000550270 / NM_206820.2; = p.E601Q on NM_002465.4) | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO5C | c.5181G>C p.M1727I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NADSYN1 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NAV1 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- NDFIP2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NEK6 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NEMF | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- NIPBL | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NPTX2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- NRCAM | c.3454G>C p.E1152Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP160 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OBSCN | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OGA | c.2458A>G p.I820V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OGA | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- OR2M2 | c.1032G>C p.M344I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5AU1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSER1 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OVCH1 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDHAC2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHAC2 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PDCD11 | c.1464C>G p.I488M | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PDE1A | c.998C>G p.S333* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- PHLPP1 | c.497C>G p.S166W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- PLPP7 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POM121L2 | c.2387G>C p.S796T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.402); called by muse, mutect2
- PRAMEF17 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, varscan2
- PRDM13 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKAA2 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCQ | c.1877G>C p.G626A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PRRC2C | c.112G>C p.V38L (on ENST00000367742; = p.A38P on NM_015172.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PTPRN2 | c.1133-1G>C p.X378_splice | Splice Site (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- RAD1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RASAL1 | c.486G>C p.W162C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- REC8 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF6 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RPLP0 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RTN4RL1 | c.558G>C p.W186C | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- SAMD15 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- SARS1 | c.588G>C p.L196F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- SCARF2 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- SCN9A | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCRIB | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SDR39U1 | c.795G>C p.Q265H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC63 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 66/479 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SHISA7 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.051); called by muse, mutect2
- SHROOM3 | c.1955C>G p.S652* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- SHTN1 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIN3A | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC25A3 | c.565C>T p.R189* (on ENST00000228318 / NM_005888.3; = p.R188* on NM_002635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2, varscan2
- SLC35E3 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- SNAPC1 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SNRPF | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SP3 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SPAG5 | c.3118-1G>A p.X1040_splice | Splice Site (SNP) | VAF 86/318 reads (27%) | called by muse, mutect2, varscan2
- SPATS2 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- SRPK2 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSBP2 | c.1077G>C p.M359I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SURF6 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SUSD2 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- SYNE1 | c.22375C>G p.Q7459E (on ENST00000367255 / NM_182961.4; = p.Q7388E on NM_033071.3) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYTL4 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TAOK2 | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- TENM2 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TENM3 | c.5884G>C p.D1962H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TESMIN | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- TET2 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- THADA | c.3252G>C p.L1084F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- TMEM191B | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TMEM59 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNS3 | c.3149C>A p.T1050N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TNS4 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOPAZ1 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, varscan2
- TP53 | c.770_782+20del p.X257_splice | Splice Site (DEL) | VAF 64/104 reads (62%) | called by mutect2, pindel
- TP53BP2 | c.1943C>G p.S648* (on ENST00000343537 / NM_001031685.3; = p.S519* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TP53BP2 | c.1309C>G p.Q437E (on ENST00000343537 / NM_001031685.3; = p.Q308E on NM_005426.2) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TPH2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TROAP | c.2336G>C p.*779Sext*1 | Nonstop Mutation (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- TTC17 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, varscan2
- TTC17 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- UBR3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.037); called by muse, mutect2
- USHBP1 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UTRN | c.9475G>A p.E3159K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- VWA1 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- WDR24 | c.2473G>T p.E825* (on ENST00000248142; = p.E695* on NM_032259.4) | Nonsense Mutation (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- WNT10A | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- YAP1 | c.1307C>T p.S436L (on ENST00000282441 / NM_001130145.3; = p.S382L on NM_006106.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- YBX1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZBED9 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZC2HC1A | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZCCHC2 | c.2390C>G p.S797* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- ZMYND19 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF17 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- ZNF268 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF563 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN26 | c.523G>A p.E175K (on ENST00000623276 / NM_001111039.2; = p.E41K on NM_152736.5) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AGPAT5 | c.927G>A p.G309= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs1186777239; called by muse, mutect2, varscan2
- ANKRD24 | c.555C>G p.L185= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, varscan2
- AP2M1 | c.321C>G p.L107= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2
- ARFGEF2 | c.282C>G p.L94= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV64214219; called by muse, mutect2
- ARG2 | c.84G>C p.V28= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- ATP8A1 | c.477G>C p.V159= | Silent (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- AUTS2 | c.3063G>A p.S1021= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- B3GAT3 | c.63C>G p.L21= | Silent (SNP) | VAF 43/211 reads (20%) | catalogued as rs761325764; called by muse, mutect2, varscan2
- CCDC69 | c.345G>A p.E115= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs754663499; called by muse, mutect2, varscan2
- CCDC88A | c.3126G>C p.L1042= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- CD46 | c.678C>G p.V226= | Silent (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- CEP112 | c.1992G>A p.L664= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV101211004; called by muse, mutect2
- CHIA | c.1170G>A p.Q390= (on ENST00000343320; = p.Q282= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV58477220; called by muse, mutect2
- CLCN6 | c.669G>A p.R223= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- CRACD | c.1074C>G p.L358= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- CSF1R | c.2895G>A p.Q965= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- DDX47 | c.672G>T p.V224= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- DDX52 | c.1209G>C p.V403= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- DNAH14 | c.9414G>A p.V3138= (on ENST00000445597; = p.V4146= on NM_001367479.1) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs1357633806; called by muse, mutect2, varscan2
- ECPAS | c.4128C>G p.V1376= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- EHMT1 | c.1281C>G p.L427= | Silent (SNP) | VAF 10/183 reads (5%) | catalogued as COSV58382253; called by muse, mutect2
- EIF3L | c.1500C>G p.L500= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs748817391; called by muse, mutect2, varscan2
- EPHA2 | c.1629C>T p.V543= | Silent (SNP) | VAF 224/406 reads (55%) | catalogued as rs369006981; called by muse, mutect2, varscan2
- EXOC6 | c.2379G>C p.L793= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV99592487; called by muse, mutect2, varscan2
- FGD1 | c.2082G>A p.T694= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs897246819; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAS8 | c.1035C>G p.L345= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs1266685219; called by muse, mutect2, varscan2
- GMPR2 | c.795C>A p.L265= (on ENST00000355299 / NM_001351022.2; = p.L283= on NM_016576.5) | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs183251921; called by muse, mutect2, varscan2
- H3C3 | c.315C>T p.F105= | Silent (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- HPCAL4 | c.435C>T p.L145= | Silent (SNP) | VAF 43/218 reads (20%) | called by muse, mutect2, varscan2
- HTRA4 | c.636C>A p.L212= | Silent (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- ICE2 | c.1413C>T p.V471= | Silent (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- IGHG3 | c.1131G>A p.L377= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- IGSF5 | c.204C>G p.L68= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as COSV66030764; called by muse, mutect2, varscan2
- IRS1 | c.2334G>A p.G778= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2, varscan2
- ITIH1 | c.144C>A p.V48= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV56251937; called by muse, mutect2, varscan2
- KCNQ5 | c.693C>T p.L231= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV59651348; called by muse, mutect2, varscan2
- KCTD8 | c.66G>C p.S22= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV63598833; called by muse, mutect2
- KLF11 | c.1506G>A p.G502= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- KLHL20 | c.1314C>T p.N438= | Silent (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- LDLR | c.1473C>T p.T491= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs558238642; called by muse, mutect2, varscan2
- LPAR4 | c.123C>G p.L41= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV70912724; called by muse, mutect2, varscan2
- MAG | c.1071C>T p.L357= | Silent (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- MCF2L | c.2493G>A p.L831= (on ENST00000375608; = p.L799= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99995931; called by muse, mutect2, varscan2
- MED25 | c.339C>G p.L113= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- MRPS21 | c.36G>A p.V12= | Silent (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- NCKAP5 | c.4725A>G p.A1575= | Silent (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- NEFH | c.45C>T p.F15= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- NHS | c.4857C>T p.S1619= | Silent (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- NKAIN3 | c.441C>G p.V147= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- NOSIP | c.804C>G p.L268= | Silent (SNP) | VAF 12/443 reads (3%) | called by muse, mutect2
- NRROS | c.1695C>A p.L565= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- NXPE3 | c.807G>C p.L269= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2
- OPA3 | c.489C>G p.L163= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55606419; called by mutect2, varscan2
- OR2V1 | c.216C>T p.L72= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- PANK1 | c.1758G>A p.G586= (on ENST00000307534 / NM_148977.2; = p.G302= on NM_138316.4) | Silent (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3756G>A p.Q1252= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV62790190; called by muse, mutect2, varscan2
- PCDHA7 | c.144C>T p.I48= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV65342235, COSV65347101; called by muse, mutect2, varscan2
- PDE3A | c.825G>C p.L275= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PKD1 | c.12438C>G p.V4146= (on ENST00000262304 / NM_001009944.3; = p.V4145= on NM_000296.4) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs772781547; called by muse, mutect2, varscan2
- POFUT1 | c.330G>A p.E110= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- PPP1R12A | c.1686G>A p.L562= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- PYCR1 | c.849G>A p.K283= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as COSV61695487; called by muse, mutect2, varscan2
- RACGAP1 | c.321C>G p.L107= | Silent (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- RGP1 | c.24C>T p.L8= | Silent (SNP) | VAF 55/301 reads (18%) | called by muse, mutect2, varscan2
- RIC8A | c.1014G>A p.L338= | Silent (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- RIMBP3 | c.2679C>T p.F893= | Silent (SNP) | VAF 62/594 reads (10%) | catalogued as rs746192696; called by muse, mutect2, varscan2
- RNF8 | c.1203C>T p.L401= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- RPE65 | c.1194C>T p.D398= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as rs139640666, COSV52019104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RPS6KA4 | c.2157G>A p.L719= | Silent (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- RPS7 | c.27G>A p.V9= | Silent (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- RREB1 | c.2202C>T p.I734= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs186395787, COSV58553338; called by muse, varscan2
- SBDS | c.57G>C p.R19= | Silent (SNP) | VAF 61/320 reads (19%) | called by muse, mutect2, varscan2
- SCMH1 | c.969G>A p.L323= (on ENST00000326197 / NM_001031694.2; = p.L276= on NM_012236.4) | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs912344150; called by muse, mutect2, varscan2
- SHPRH | c.4137C>T p.I1379= (on ENST00000275233 / NM_001042683.3; = p.I1383= on NM_173082.3) | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- SLC10A7 | c.453C>A p.P151= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs764392225; called by muse, mutect2, varscan2
- SLC16A8 | c.1179C>T p.L393= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1473600279; called by muse, mutect2, varscan2
- SLC25A29 | c.414C>T p.L138= (on ENST00000359232 / NM_001039355.3; = p.L72= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs1201704174; called by muse, mutect2, varscan2
- SLC26A4 | c.1521G>A p.L507= | Silent (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- SLC27A5 | c.756C>G p.L252= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as COSV54021995; called by muse, mutect2
- SOCS7 | c.930G>C p.A310= | Silent (SNP) | VAF 21/301 reads (7%) | called by muse, mutect2
- SPTBN1 | c.4299G>A p.K1433= | Silent (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- STOX2 | c.228G>A p.E76= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- SURF4 | c.750C>G p.L250= | Silent (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- TAF1L | c.5025C>T p.L1675= | Silent (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- TBATA | c.1055G>A p.*352= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as rs1351091434; called by muse, mutect2, varscan2
- TCF3 | c.1374C>G p.L458= | Silent (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- TGM1 | c.2250G>A p.V750= | Silent (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- TMEM25 | c.282C>T p.F94= | Silent (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- TMEM79 | c.888C>T p.F296= | Silent (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- TNFRSF10A | c.285C>T p.V95= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs376175057; called by muse, mutect2, varscan2
- TRIM15 | c.21G>A p.L7= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- TRIM5 | c.102C>T p.F34= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- TTLL10 | c.837G>T p.L279= (on ENST00000379289 / NM_001130045.2; = p.L206= on NM_153254.3) | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.2067C>T p.F689= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs759663668, COSV99428228; called by muse, mutect2, varscan2
- VIRMA | c.157C>T p.L53= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV52589106; called by muse, mutect2
- WDR18 | c.750G>A p.Q250= | Silent (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- WNK3 | c.4536C>G p.L1512= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- ZDHHC6 | c.309C>T p.V103= | Silent (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- ZNF251 | c.258C>T p.I86= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- ZNF324 | c.1599G>A p.A533= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as rs377733639; called by muse, mutect2, varscan2
- ZNF354C | c.1188T>A p.I396= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- ZNF814 | c.687C>G p.L229= | Silent (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.1284G>C p.L428= | Silent (SNP) | VAF 30/303 reads (10%) | called by muse, mutect2, varscan2
- ZXDB | c.1035C>T p.F345= | Silent (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*833+44_*833+63del | Intron (DEL) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- ADD1 | c.1605+732C>G | Intron (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- ADGRA1 | chr10:133085009 C>G | 5'Flank (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2
- ADGRE4P | n.1162G>A | RNA (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- AIRE | c.880-133G>C | Intron (SNP) | VAF 56/312 reads (18%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.99+60C>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- ANKRD55 | c.965+2395G>C | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- AP000311.1 | c.-30C>A | 5'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506182 G>C | 3'Flank (SNP) | VAF 10/28 reads (36%) | catalogued as rs1191106140; called by muse, mutect2, varscan2
- AP1G2 | c.-60G>T | 5'UTR (SNP) | VAF 20/84 reads (24%) | catalogued as COSV58113041; called by muse, mutect2
- AP1S1 | c.*167C>G | 3'UTR (SNP) | VAF 39/281 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.261+240G>C | Intron (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- ARHGAP27P2 | n.295C>T | RNA (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- ASH1L | c.-127C>G | 5'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ATL2 | c.119-15159C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs532118560; called by muse, varscan2
- BET1 | c.*309C>G | 3'UTR (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- BTNL10 | n.451G>T | RNA (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- C2orf81 | c.477+11C>G | Intron (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- C9orf106 | n.71G>C | RNA (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- CARF | c.1332-825G>C | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- CCDC144CP | n.1887G>C | RNA (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- CDH4 | c.170-24417G>C | Intron (SNP) | VAF 7/81 reads (9%) | catalogued as rs1209357050; called by muse, mutect2
- CHFR | chr12:132836802 C>G | 3'Flank (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- CLK4 | c.162-1078A>G | Intron (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- CYP27B1 | c.*41C>T | 3'UTR (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- DNM2 | c.2059-38G>A | Intron (SNP) | VAF 27/113 reads (24%) | catalogued as rs771746281; called by muse, mutect2, varscan2
- EIF4G1 | c.-91-35G>A | Intron (SNP) | VAF 85/424 reads (20%) | called by muse, mutect2, varscan2
- EIF4G1 | c.-91-34G>A | Intron (SNP) | VAF 86/425 reads (20%) | catalogued as rs939352176; called by muse, mutect2, varscan2
- ERAL1 | chr17:28861544 G>C | 3'Flank (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
- FAM90A20P | n.234G>A | RNA (SNP) | VAF 37/282 reads (13%) | called by muse, mutect2, varscan2
- FANCD2 | chr3:10101216 G>A | 3'Flank (SNP) | VAF 10/122 reads (8%) | catalogued as COSV55045212; called by muse, mutect2
- FCHSD2 | c.924+2250C>G | Intron (SNP) | VAF 20/108 reads (19%) | catalogued as COSV60808242; called by muse, mutect2, varscan2
- FIGNL2 | c.*53C>T | 3'UTR (SNP) | VAF 14/85 reads (16%) | called by mutect2, varscan2
- GNA12 | c.310-19736C>T | Intron (SNP) | VAF 14/86 reads (16%) | catalogued as rs761755558; called by muse, mutect2, varscan2
- GNL1 | c.*63C>G | 3'UTR (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- HAUS7 | chrX:153471047 C>T | 5'Flank (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- HMG20B | c.147+46C>G | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs766360451; called by muse, varscan2
- IFT27 | c.352+52C>G | Intron (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- IMPDH1 | c.-39C>A | 5'UTR (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- KCNH2 | c.2398+132C>T | Intron (SNP) | VAF 52/193 reads (27%) | catalogued as rs901996408; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46375C>A | Intron (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- KIF9 | c.981+422G>C | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- LINC01619 | n.1312C>G | RNA (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-3913G>T | Intron (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- MSRA | c.-16C>T | 5'UTR (SNP) | VAF 40/184 reads (22%) | catalogued as COSV57802255; called by muse, mutect2, varscan2
- NEB | c.8890-445G>C | Intron (SNP) | VAF 17/137 reads (12%) | catalogued as COSV99426524; called by muse, mutect2, varscan2
- NKD1 | c.193-1440C>A | Intron (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- RAB34 | c.-55G>A | 5'UTR (SNP) | VAF 79/272 reads (29%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.537+5892C>T | Intron (SNP) | VAF 11/63 reads (17%) | catalogued as rs1269564584; called by muse, mutect2, varscan2
- RPS26P15 | n.329C>T | RNA (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- RTN4 | c.3013+14941G>C | Intron (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- SCYL1 | c.2302+25G>T | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- SH3BP2 | c.429-131C>T | Intron (SNP) | VAF 74/232 reads (32%) | called by muse, mutect2, varscan2
- SLC16A6P1 | n.736G>C | RNA (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- SLC25A29 | c.*20C>T | 3'UTR (SNP) | VAF 28/174 reads (16%) | catalogued as rs758004690; called by muse, mutect2, varscan2
- SULT1E1 | c.496+34C>T | Intron (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- TAF10 | c.*1236C>T | 3'UTR (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- TEX36-AS1 | n.514+425C>G | Intron (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- TRMT13 | c.*298C>G | 3'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as rs375861468; called by muse, mutect2, varscan2
- TTC23L | c.*36G>A | 3'UTR (SNP) | VAF 24/110 reads (22%) | catalogued as rs754704707; called by muse, mutect2, varscan2
- UBTF | c.-64G>A | 5'UTR (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
